Gene-level copy-number profile of tumor specimen C3L-01330-01 (profiled together with C3L-01330-02) from CPTAC case C3L-01330, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,076 days).
Specimen C3L-01330-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3aa58c01-67cb-4ae7-b92e-8952f4110d02.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01330-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/b82577e0-0f2d-407e-ba77-147e8d307814

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 12,304; copy number 2: 37,812; copy number 3: 7,703; copy number 4: 190; copy number 5: 160; copy number 6: 82; copy number 7: 98; copy number 8: 12; copy number 9: 43.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,418,775–18,419,273, 1 gene: BNIP3P6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 395 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:47,333,797–48,497,736, 27 genes, copy number 6: CMPK1, LINC01389, FOXE3, FOXD2-AS1, FOXD2, AL356458.1, RPL21P24, ATP6V0E1P4, LINC01738, TRABD2B, AL691459.1, AC096541.1, LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2, AL109659.1, SLC5A9, AL109659.2, AL109659.3, SPATA6, PPP1R8P1, RNU6-723P, AL356968.2, RNU4-61P, AL356968.1.
- chr8:58,490,178–59,893,942, 17 genes, copy number 7: CYP7A1, PPIAP85, SDCBP, NSMAF, AC068522.1, TOX, RNU4-50P, AC105150.1, AC090152.1, AC087698.1, RNA5SP267, AC087664.3, AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1.
- chr8:97,241,742–106,981,571, 192 genes, copy number 5–9 (broad region; genes not listed).
- chr8:110,334,743–111,236,203, 10 genes, copy number 5–6: AC073023.1, AC090819.1, AC025366.1, AP005357.1, NDUFB9P3, LINC01608, MTCO1P47, LINC01609, AC009930.1, EEF1A1P37.
- chr8:131,129,761–137,092,183, 64 genes, copy number 5–6 (broad region; genes not listed).
- chr8:137,809,444–138,914,041, 5 genes, copy number 5: AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1.
- chr8:142,834,247–144,143,664, 79 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:18,395,626–18,412,264, 1 gene, copy number 5: CR383658.2.

Autosomal genes at a single copy (total copy number 1): 12,304. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
